Somatic mutation profile of tumor specimen TCGA-MP-A4SV-01A (aliquot TCGA-MP-A4SV-01A-11D-A24P-08) from TCGA case TCGA-MP-A4SV, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.1 years (24,516 days).
Specimen TCGA-MP-A4SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84ecfc5d-2c5e-4891-82d2-d984ad9d509b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4SV-10A (Blood Derived Normal), aliquot TCGA-MP-A4SV-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f05891b-cb21-4eed-8029-6e1e3e0407df

The open-access MAF lists 362 somatic variants for this specimen: 266 protein-altering or splice-affecting, 87 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 87, Nonsense Mutation 18, Splice Site 10, Intron 5, Frame Shift Del 5, Splice Region 3, Frame Shift Ins 2, 5'Flank 2, In Frame Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH2 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121912504, CM950709, COSV51212273; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55287764; called by muse, mutect2, varscan2
- ABCC9 | c.3271C>A p.L1091M | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99684030; called by muse, mutect2, varscan2
- ABHD17B | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV100329976; called by muse, mutect2, varscan2
- ACKR2 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99825299; called by muse, mutect2, varscan2
- ACTC1 | c.1099G>C p.A367P | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.341); catalogued as COSV99291535; called by muse, mutect2, varscan2
- ACTN3 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100074035; called by muse, mutect2
- ACTRT2 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101007438, COSV65760464; called by muse, mutect2, varscan2
- ADAT2 | c.401G>C p.C134S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99395551; called by muse, mutect2, varscan2
- ADGRL4 | c.1139T>A p.M380K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV100875485; called by muse, mutect2
- ADH1A | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99265619, COSV99265964; called by muse, mutect2, varscan2
- AGO3 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV99867819; called by muse, mutect2, varscan2
- AGRN | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as COSV101038507, COSV65069204; called by muse, mutect2, varscan2
- AHNAK | c.12884G>T p.G4295V | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs1257955272, COSV99945160, COSV99949857; called by muse, mutect2, varscan2
- AIPL1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs201520235, COSV51508806; called by muse, mutect2, varscan2
- AKR1D1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs867626075, COSV99652736; called by muse, mutect2
- ALOX5 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100979910, COSV100980166; called by muse, mutect2, varscan2
- ANO5 | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.977); catalogued as CM129936, COSV100201270, COSV61088254; called by muse, mutect2
- ARVCF | c.1286A>G p.Y429C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758765047, COSV99598841; called by muse, mutect2
- ATRNL1 | c.1250A>G p.H417R | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100743586; called by muse, mutect2, varscan2
- AXDND1 | c.1701G>T p.E567D | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV100858229; called by muse, mutect2, varscan2
- B4GALNT2 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs761855709, COSV100302327; called by muse, mutect2, varscan2
- BDKRB2 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.241); catalogued as COSV100020826, COSV100020866; called by muse, mutect2, varscan2
- BEND6 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV100876715; called by muse, mutect2
- BMF | c.287T>A p.F96Y | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99590313; called by muse, mutect2
- BNC2 | c.3177G>C p.L1059F | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66170042; called by muse, mutect2
- CACNA2D4 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99764889; called by muse, mutect2, varscan2
- CAPN1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV99658263; called by muse, mutect2, varscan2
- CASP1 | c.8-1G>T p.X3_splice | Splice Site (SNP) | VAF 22/324 reads (7%) | catalogued as COSV100782673; called by muse, mutect2
- CCL16 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs1234722629; called by muse, mutect2
- CDC6 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99266470; called by muse, mutect2
- CFAP65 | c.5401G>C p.E1801Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as COSV100444414; called by muse, mutect2
- CHRDL1 | c.1119G>C p.W373C (on ENST00000372045; = p.W379C on NM_145234.4) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54323629, COSV99487592; called by muse, mutect2
- CIT | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as COSV55865538, COSV99948015; called by muse, mutect2, varscan2
- CMTR2 | c.1495G>T p.G499* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100578925; called by muse, mutect2, varscan2
- CNTN2 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1330386390, COSV59351376; called by mutect2, varscan2
- COL11A1 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100614433, COSV62179770; called by muse, mutect2, varscan2
- COL11A1 | c.2584G>T p.G862C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62179137; called by muse, mutect2, varscan2
- CPXCR1 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99341898; called by muse, mutect2, varscan2
- CRHBP | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs768709074, COSV57189014; called by muse, mutect2, varscan2
- CRISP3 | c.777G>T p.Q259H (on ENST00000371159 / NM_001368123.1; = p.Q241H on NM_006061.4) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as COSV99538514; called by muse, mutect2, varscan2
- CSMD2 | c.7553T>A p.L2518Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs754544882, COSV99584426; called by muse, mutect2, varscan2
- CSMD3 | c.2506G>T p.D836Y (on ENST00000297405 / NM_001363185.1; = p.D732Y on NM_052900.3) | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99820880; called by muse, mutect2
- CSPP1 | c.1174G>T p.A392S (on ENST00000676605; = p.A351S on NM_024790.6) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1394567085, COSV99137932; called by muse, mutect2, varscan2
- CYP4F2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99171031; called by muse, mutect2
- DCAF4L2 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV100150369; called by muse, mutect2, varscan2
- DDX27 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs1377240943, COSV100874628; called by muse, mutect2
- DEPTOR | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV99637637; called by muse, mutect2
- DGKD | c.2108C>T p.P703L (on ENST00000264057 / NM_152879.3; = p.P659L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs896873247, COSV99894992; called by muse, mutect2
- DKK2 | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV53403524, COSV99567989; called by muse, mutect2, varscan2
- DMWD | c.1938A>T p.E646D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.023); catalogued as COSV99352614; called by muse, mutect2, varscan2
- DOCK9 | c.5251G>C p.E1751Q (on ENST00000376460 / NM_001366676.2; = p.E1752Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV100237422; called by muse, mutect2, varscan2
- DPY19L2 | c.336C>T p.I112= | Splice Region (SNP) | VAF 10/98 reads (10%) | catalogued as rs1490654554, COSV100116399, COSV100116653; called by muse, mutect2
- DUSP6 | c.698T>A p.I233N | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99683904; called by muse, mutect2, varscan2
- DYRK1A | c.1912A>T p.N638Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV100117323; called by muse, mutect2, varscan2
- ELOA | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV101403568; called by muse, mutect2
- ELOA | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.368); catalogued as COSV101403570; called by muse, mutect2
- EP400 | c.6466G>T p.A2156S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100200079, COSV57787030; called by muse, mutect2, varscan2
- EPB41L3 | c.854A>G p.H285R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1249621070, COSV100547937; called by muse, mutect2
- EPHA3 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV100341781; called by muse, mutect2, varscan2
- ERBB4 | c.3541C>T p.Q1181* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV61507275; called by muse, mutect2
- EYS | c.1459G>T p.G487* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV60985217; called by muse, varscan2
- FAAP24 | c.166T>C p.C56R | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs755566798, COSV99578767; called by muse, mutect2, varscan2
- FAM13A | c.2411A>T p.E804V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99982663; called by muse, mutect2, varscan2
- FAM71B | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100261681; called by muse, mutect2, varscan2
- FBXL17 | c.1375-2A>G p.X459_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100670237; called by muse, mutect2, varscan2
- FBXL3 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100842308; called by muse, mutect2, varscan2
- FLG | c.6144G>T p.E2048D | Missense Mutation (SNP) | VAF 224/762 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs750914357, COSV100910303; called by muse, mutect2, varscan2
- FN1 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100115463; called by muse, mutect2
- FOCAD | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV100619881; called by muse, mutect2
- FRAS1 | c.8182G>T p.G2728C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99347117; called by muse, mutect2, varscan2
- GAPDH | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV99975341; called by muse, mutect2, varscan2
- GJA4 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654601; called by muse, mutect2, varscan2
- GOLGA3 | c.3350A>G p.E1117G | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99201805; called by muse, mutect2
- GOLGB1 | c.5006A>C p.Q1669P | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs537556767, COSV100510182; called by muse, mutect2
- GPR174 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337891; called by muse, mutect2, varscan2
- GRIA4 | c.1848-1G>T p.X616_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99228022; called by muse, mutect2, varscan2
- GRIK2 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100021892; called by muse, mutect2, varscan2
- GTDC1 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893470892, COSV99599075; called by muse, mutect2
- H2AC14 | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100297437, COSV60798867; called by muse, mutect2
- HAT1 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV51362442, COSV99907724; called by muse, mutect2, varscan2
- HAUS3 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99704097; called by muse, mutect2, varscan2
- HAUS3 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as rs1302762214, COSV99704099; called by muse, mutect2
- HBP1 | c.1532C>G p.S511* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99752901; called by muse, mutect2, varscan2
- HCFC2 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99982808; called by muse, mutect2
- HLTF | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV100026650; called by muse, mutect2
- HPX | c.967-1G>T p.X323_splice | Splice Site (SNP) | VAF 12/164 reads (7%) | catalogued as COSV99793146; called by muse, mutect2
- IGHV1-58 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs370108530; called by muse, mutect2, varscan2
- IL22RA1 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99582645; called by muse, mutect2
- IL36B | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.194); catalogued as rs1351275384; called by muse, mutect2
- ILF3 | c.2437G>T p.G813* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | catalogued as COSV99139279; called by muse, mutect2, varscan2
- IMPG1 | c.1555C>A p.L519I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV64059789; called by muse, mutect2, varscan2
- JAK2 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67600242; called by muse, mutect2, varscan2
- KDM5C | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.046); catalogued as COSV100948694; called by muse, mutect2, varscan2
- KIAA1109 | c.11188G>A p.E3730K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV99145352; called by muse, mutect2, varscan2
- KIAA1614 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100851143; called by muse, mutect2, varscan2
- KIF20B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99589301; called by muse, mutect2, varscan2
- KIF2B | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV99274446; called by muse, mutect2, varscan2
- KLHL32 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.663); catalogued as COSV100987042; called by muse, mutect2, varscan2
- KLHL4 | c.717T>G p.Y239* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100909005; called by muse, mutect2, varscan2
- KLHL4 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV100909006; called by muse, mutect2, varscan2
- KPNB1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99267695; called by muse, mutect2, varscan2
- KRT4 | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV99542514; called by muse, mutect2, varscan2
- KRT77 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100526881; called by muse, mutect2, varscan2
- LAMA2 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70356169; called by muse, mutect2, varscan2
- LAMA4 | c.3467G>A p.R1156K (on ENST00000230538 / NM_001105206.3; = p.R1149K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.474); catalogued as rs782725292, COSV57906442; called by muse, mutect2, varscan2
- LCMT2 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs749847027, COSV99979862; called by muse, mutect2, varscan2
- LGMN | c.62A>G p.D21G | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100605663; called by muse, mutect2, varscan2
- LIMK1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100283228, COSV60283820; called by muse, mutect2, varscan2
- LRFN4 | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1297507742, COSV100540607; called by muse, mutect2
- LRIG2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs771022906, COSV100742898; called by muse, mutect2, varscan2
- LRP4 | c.5327T>A p.V1776E | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101066091; called by muse, mutect2, varscan2
- LRRTM1 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV99701565; called by muse, mutect2
- LYPD1 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100489403; called by muse, mutect2
- LYST | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as rs1362991461, COSV101087786; called by muse, mutect2
- MALT1 | c.2146G>C p.D716H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100618527; called by muse, mutect2, varscan2
- MAML3 | c.1932G>T p.Q644H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.121); catalogued as rs1259329070, COSV100504869, COSV100505052; called by muse, mutect2
- MAMLD1 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as COSV99475417; called by muse, mutect2, varscan2
- MAP2 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV99557278; called by muse, mutect2, varscan2
- MAP3K12 | c.2194C>A p.L732M | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV99912812; called by muse, mutect2
- MFSD9 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs372925047, COSV51492718; called by muse, mutect2
- MGAM | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749121609, COSV72073544; called by muse, mutect2, varscan2
- MRPL14 | c.72-1G>A p.X24_splice | Splice Site (SNP) | VAF 14/230 reads (6%) | catalogued as COSV100921017; called by muse, mutect2
- MS4A4A | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100557689; called by muse, mutect2, varscan2
- MYBBP1A | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99625174; called by muse, mutect2
- MYH13 | c.1951G>T p.V651L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs377381885, COSV99351699; called by muse, mutect2, varscan2
- MYO16 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51819093, COSV99193403; called by muse, mutect2, varscan2
- MYO3A | c.4436C>T p.S1479L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV99777674; called by muse, mutect2
- MYOCD | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28730822; called by muse, mutect2, varscan2
- NAV2 | c.410A>C p.N137T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100584412, COSV62326993; called by muse, mutect2, varscan2
- NAV3 | c.3467G>A p.R1156K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57081684; called by muse, mutect2
- NCOA6 | c.1494C>G p.N498K | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV100749873; called by muse, mutect2, varscan2
- NCOR1 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV51968381, COSV99246356; called by muse, mutect2
- NEXMIF | c.3554G>T p.G1185V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99279282; called by muse, mutect2
- NLGN4X | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.619); catalogued as COSV52024851; called by muse, mutect2, varscan2
- NLRP1 | c.4152G>T p.Q1384H (on ENST00000572272 / NM_033004.4; = p.Q1340H on NM_014922.5) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52558193; called by muse, mutect2, varscan2
- NLRP6 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100380900; called by muse, mutect2
- NPAP1 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as COSV61511810, COSV61512424; called by muse, mutect2
- NR3C2 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1442188316, COSV100678561; called by muse, mutect2, varscan2
- OLFM4 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99524143; called by muse, mutect2, varscan2
- OPA1 | c.2925T>A p.D975E (on ENST00000361510 / NM_130837.3; = p.D920E on NM_015560.3) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.742); catalogued as COSV100655090; called by muse, mutect2, varscan2
- OPA1 | c.2926G>T p.G976C (on ENST00000361510 / NM_130837.3; = p.G921C on NM_015560.3) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752986280, COSV100655092; called by muse, mutect2, varscan2
- OR10A6 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100564221; called by muse, mutect2
- OR2F2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as COSV101283788; called by muse, mutect2, varscan2
- OR2M3 | c.485C>A p.A162E | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV101513385, COSV71759003; called by muse, mutect2
- OR2M3 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71759375; called by muse, mutect2, varscan2
- OR4A15 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV59035689; called by mutect2, varscan2
- OR4C46 | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100060514, COSV60220454; called by muse, mutect2, varscan2
- OR4C6 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.45); catalogued as rs769704448, COSV100051306, COSV58604575; called by muse, mutect2, varscan2
- OR4K2 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100063916; called by muse, mutect2, varscan2
- OR51S1 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100437315; called by muse, mutect2
- OR5B3 | c.771C>G p.Y257* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as rs757571516, COSV100511755; called by muse, mutect2, varscan2
- OR6K3 | c.370G>A p.E124K (on ENST00000368146; = p.E108K on NM_001005327.2) | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63746475; called by muse, mutect2
- OR6Y1 | c.443C>A p.T148K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV100225206; called by muse, mutect2, varscan2
- OR8U1 | c.245T>A p.L82H | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100163680; called by muse, varscan2
- OR8U1 | c.502T>G p.Y168D | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100163682; called by muse, mutect2
- OSBPL1A | c.1747T>C p.Y583H (on ENST00000319481 / NM_080597.4; = p.Y70H on NM_018030.4) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100110892; called by muse, mutect2
- OTOF | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV99716179; called by muse, mutect2, varscan2
- OTOR | c.116-1G>T p.X39_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99856103; called by muse, mutect2
- P4HB | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515704; called by muse, mutect2, varscan2
- PAPPA2 | c.2363C>G p.P788R | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100866421; called by muse, mutect2, varscan2
- PCDH11Y | c.1580G>T p.S527I (on ENST00000400457 / NM_032973.2; = p.S516I on NM_032971.3) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1569475042, COSV99290245; called by muse, mutect2
- PCDHA3 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as COSV100793067, COSV63543102; called by muse, mutect2, varscan2
- PCDHB7 | c.1521C>A p.N507K | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50770408, COSV99175197; called by muse, mutect2, varscan2
- PCLO | c.8075G>A p.S2692N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV100426257; called by muse, mutect2
- PCSK1 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226742; called by muse, mutect2, varscan2
- PDZD2 | c.863G>C p.R288T | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99223219; called by muse, mutect2
- PHIP | c.4924A>T p.K1642* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV99243198; called by muse, mutect2, varscan2
- PIAS3 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as COSV100992586; called by muse, mutect2
- PIK3C2A | c.3415-2A>T p.X1139_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99790044; called by muse, mutect2, varscan2
- PKDREJ | c.5665C>A p.Q1889K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99478266; called by muse, mutect2, varscan2
- PLD1 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577465; called by muse, mutect2
- PLEKHB2 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52175579; called by muse, mutect2
- PLIN4 | c.2867G>A p.G956E (on ENST00000301286; = p.G971E on NM_001367868.2) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV100012555; called by muse, mutect2, varscan2
- PNMA8A | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs1403252785, COSV100562240; called by muse, mutect2
- POLQ | c.7644A>T p.E2548D | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV99951366; called by muse, mutect2, varscan2
- POU3F4 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV100937141; called by muse, mutect2, varscan2
- PPP2R2A | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100276884; called by muse, mutect2, varscan2
- PRKD1 | c.415T>A p.F139I | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as COSV100118980; called by muse, mutect2
- PRKG1 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV100907599; called by muse, mutect2
- PROSER1 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100612582; called by muse, mutect2, varscan2
- PRUNE2 | c.6253G>A p.E2085K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100944169; called by muse, mutect2
- PSG8 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 85/375 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100125913; called by muse, mutect2, varscan2
- PSKH2 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV52609037; called by muse, mutect2, varscan2
- PTGER3 | c.1077+5C>G | Splice Region (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100137955; called by muse, mutect2, varscan2
- RAB3GAP2 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99424320; called by muse, mutect2, varscan2
- RAD51D | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238899; called by muse, mutect2, varscan2
- RECQL | c.366T>A p.C122* | Nonsense Mutation (SNP) | VAF 28/115 reads (24%) | catalogued as COSV100131086; called by muse, mutect2, varscan2
- RELN | c.1956G>C p.W652C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100631920; called by muse, mutect2
- ROR2 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995360; called by muse, mutect2, varscan2
- RP1L1 | c.5551G>T p.V1851L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101222841; called by muse, mutect2, varscan2
- RYR2 | c.5662C>G p.R1888G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100767155; called by muse, mutect2, varscan2
- SCN8A | c.2025G>C p.K675N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV100633002; called by muse, mutect2
- SEMA3E | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100316853; called by muse, mutect2
- SEMA6B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs758370327, COSV100014569; called by muse, mutect2, varscan2
- SERINC1 | c.371+1G>C p.X124_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100305000; called by muse, mutect2, varscan2
- SGCB | c.662A>T p.D221V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.361); catalogued as COSV101197592; called by muse, mutect2, varscan2
- SLC10A4 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs758462234, COSV56718122, COSV99906739; called by mutect2, varscan2
- SLC12A5 | c.439G>A p.V147M (on ENST00000454036 / NM_001134771.2; = p.V124M on NM_020708.5) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99715087; called by muse, mutect2, varscan2
- SLC12A6 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100824923; called by muse, mutect2
- SLC19A2 | c.1466A>T p.Q489L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99356759; called by muse, mutect2, varscan2
- SLC24A4 | c.680T>A p.V227E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV100103941; called by muse, mutect2, varscan2
- SLC25A2 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV99508123; called by muse, mutect2, varscan2
- SLC26A7 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99402250; called by muse, mutect2, varscan2
- SLC32A1 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV54147145; called by muse, mutect2, varscan2
- SLC8A1 | c.2542C>G p.P848A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100243959; called by muse, mutect2, varscan2
- SLC9A2 | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 19/256 reads (7%) | catalogued as COSV99295696; called by muse, mutect2
- SMIM21 | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV101232283; called by muse, mutect2, varscan2
- SOS2 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV53572054, COSV99365202; called by muse, mutect2
- SPAG17 | c.6014C>A p.S2005Y | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.127); catalogued as COSV100307475; called by muse, mutect2, varscan2
- SPAM1 | c.1373G>C p.C458S | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56147280, COSV99033870; called by muse, mutect2, varscan2
- SPPL3 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100793525; called by muse, mutect2
- SSX3 | c.428del p.G143Efs*11 | Frame Shift Del (DEL) | VAF 114/229 reads (50%) | catalogued as COSV100035591; called by mutect2, pindel, varscan2
- ST18 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99387711; called by muse, mutect2, varscan2
- STK17B | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99825944; called by muse, mutect2, varscan2
- SUPT7L | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as COSV100389095; called by muse, mutect2, varscan2
- SYF2 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.844); catalogued as rs775601338, COSV52573321; called by muse, mutect2, varscan2
- TCHH | c.4916A>C p.Q1639P | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV100914845; called by muse, mutect2, varscan2
- TEFM | c.506G>C p.S169T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100034902; called by muse, varscan2
- TENM1 | c.3521A>T p.N1174I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100948769; called by muse, mutect2, varscan2
- TENM3 | c.2251G>T p.G751* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101304657; called by muse, mutect2, varscan2
- TLR2 | c.1282A>C p.M428L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV99472024; called by muse, mutect2, varscan2
- TRIM58 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100824780; called by muse, mutect2
- TRPV6 | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.272); catalogued as rs769647587, COSV100844050; called by muse, mutect2, varscan2
- TTN | c.14584G>A p.A4862T (on ENST00000591111; = p.A3935T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | PolyPhen benign (0.025); catalogued as rs536853382, COSV100589293; called by muse, mutect2, varscan2
- TUBA1C | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99988601; called by muse, mutect2
- TUBB6 | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99301398; called by muse, mutect2
- USH2A | c.2411C>A p.P804H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100227637; called by muse, mutect2, varscan2
- USP6 | c.965G>C p.R322P | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.152); catalogued as COSV100002722; called by muse, mutect2, varscan2
- VANGL2 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV100925503; called by muse, mutect2
- VAV3 | c.1915-1G>T p.X639_splice | Splice Site (SNP) | VAF 8/70 reads (11%) | catalogued as rs1471473935, COSV100578929, COSV58378873; called by muse, mutect2, varscan2
- WDR25 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV100091147; called by muse, mutect2
- WNK4 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99889160; called by muse, mutect2, varscan2
- ZBTB41 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100962730; called by muse, mutect2, varscan2
- ZBTB41 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100962732; called by muse, mutect2, varscan2
- ZDBF2 | c.2444T>C p.V815A | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV100984256; called by muse, mutect2
- ZER1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV52564425; called by muse, mutect2
- ZFP69B | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100848182; called by muse, mutect2
- ZFPM2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438004050, COSV101022912; called by muse, mutect2
- ZMIZ1 | c.1230G>A p.E410= | Splice Region (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100565811; called by muse, mutect2
- ZNF256 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99990535; called by muse, mutect2
- ZNF470 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375218755; called by muse, mutect2, varscan2
- ZNF507 | c.1189G>C p.V397L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100321471; called by mutect2, varscan2
- ZNF587 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as COSV100299238; called by muse, mutect2, varscan2
- ZNF646 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs1396065222, COSV99761946; called by muse, mutect2
- ACTN3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADAP1 | c.458dup p.T154Dfs*14 | Frame Shift Ins (INS) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- ARL10 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- ASAH2 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CBLN4 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- COL21A1 | c.2366C>A p.S789* | Nonsense Mutation (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- EXOC3 | c.1276_1278dup p.A426dup | In Frame Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- GPR171 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2
- H1-5 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IGKV3D-20 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- LRRC4C | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- OR4A15 | c.240dup p.V81Cfs*2 | Frame Shift Ins (INS) | VAF 30/191 reads (16%) | called by mutect2, pindel, varscan2
- OR51D1 | c.465del p.K156Rfs*7 | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- PDP2 | c.1347del p.L450Sfs*25 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- PHKB | c.1915del p.A639Qfs*7 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- SLC5A7 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- STAT5A | c.2381_*2del | Nonstop Mutation (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- TMEM236 | c.473-1G>T p.X158_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- ZNF677 | c.1308_1309del p.C436Wfs*26 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- ADAM12 | c.2592C>A p.A864= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100902707; called by muse, mutect2, varscan2
- ADAMTS20 | c.4638A>G p.S1546= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV101238681; called by muse, mutect2, varscan2
- ASXL3 | c.5839C>T p.L1947= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99322813; called by muse, mutect2
- BRD1 | c.324C>T p.H108= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs138837185; called by muse, mutect2, varscan2
- CCNB3 | c.675C>A p.T225= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99328293; called by muse, mutect2, varscan2
- CELSR3 | c.5589G>C p.R1863= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV99372185; called by muse, mutect2, varscan2
- CFAP53 | c.522G>A p.K174= | Silent (SNP) | VAF 85/263 reads (32%) | catalogued as COSV101274929; called by muse, mutect2, varscan2
- CPS1 | c.892T>C p.L298= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV51820075; called by muse, mutect2
- CSN2 | c.576T>A p.P192= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100778700; called by muse, mutect2, varscan2
- CUX1 | c.2721G>A p.Q907= | Silent (SNP) | VAF 7/134 reads (5%) | catalogued as COSV99470008; called by muse, mutect2
- DCC | c.1452C>A p.S484= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100497435, COSV59092666; called by muse, mutect2, varscan2
- DHX16 | c.831G>T p.R277= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100905101; called by muse, mutect2
- DOCK5 | c.3360C>T p.L1120= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs760061661, COSV52416292; called by muse, mutect2, varscan2
- FADS6 | c.366C>A p.T122= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100043877, COSV59603988; called by muse, mutect2
- FAM114A2 | c.1161C>T p.A387= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100697548, COSV61078650; called by muse, mutect2, varscan2
- FAM161B | c.1261C>T p.L421= (on ENST00000651776; = p.L358= on NM_152445.3) | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as COSV99679474; called by muse, mutect2
- FCGBP | c.10347C>T p.C3449= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- GABBR1 | c.2076C>T p.F692= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as rs1051160819, COSV100589733; called by muse, mutect2
- GABPA | c.480A>T p.S160= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- GAS2L3 | c.1113T>C p.S371= | Silent (SNP) | VAF 45/144 reads (31%) | catalogued as COSV99902630; called by muse, mutect2, varscan2
- GPATCH8 | c.2292G>A p.G764= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV100132383; called by muse, mutect2
- HAUS5 | c.1098G>A p.Q366= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99177706; called by muse, mutect2, varscan2
- HDAC4 | c.543T>C p.N181= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100612490; called by muse, mutect2, varscan2
- HECW1 | c.3457C>A p.R1153= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as COSV67840087; called by muse, mutect2, varscan2
- HS2ST1 | c.834C>G p.L278= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100777599; called by muse, mutect2
- IFNA13 | c.243C>A p.L81= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV101489457; called by muse, mutect2, varscan2
- IGKV2D-24 | c.168C>A p.T56= | Silent (SNP) | VAF 46/158 reads (29%) | called by muse, mutect2, varscan2
- IL20RB | c.153C>G p.L51= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs1203681729, COSV100290897; called by muse, mutect2
- IRF3 | c.591G>A p.V197= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99880784; called by muse, mutect2, varscan2
- ITPR2 | c.2898G>C p.V966= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV101189755; called by muse, mutect2
- KBTBD6 | c.510G>A p.L170= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV101068674; called by muse, mutect2, varscan2
- KIAA1217 | c.4917G>A p.R1639= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100285989; called by muse, mutect2, varscan2
- LHX9 | c.315C>T p.L105= | Silent (SNP) | VAF 24/304 reads (8%) | catalogued as rs1331764808, COSV100435559; called by muse, mutect2
- LILRA2 | c.1443C>A p.A481= (on ENST00000391738 / NM_001130917.3; = p.A464= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV52192438, COSV99252531; called by muse, mutect2, varscan2
- LIMK1 | c.1026G>T p.G342= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100282922; called by muse, mutect2, varscan2
- LONP1 | c.1224C>G p.G408= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100638492, COSV62261144; called by muse, mutect2, varscan2
- LPCAT3 | c.1023C>T p.T341= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV99780919; called by muse, mutect2
- LPIN3 | c.2331G>A p.V777= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100182253; called by muse, mutect2
- LRP2 | c.9150C>T p.V3050= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99785889; called by muse, mutect2
- MAGEB2 | c.816A>G p.Q272= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs768025185, COSV100975546; called by muse, mutect2, varscan2
- MFAP3L | c.558C>T p.I186= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV100852599; called by muse, mutect2
- MUC17 | c.4623C>T p.T1541= | Silent (SNP) | VAF 33/406 reads (8%) | catalogued as rs776931891, COSV100071101; called by muse, mutect2
- MYO1A | c.9C>A p.L3= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100270432; called by muse, mutect2
- NFAT5 | c.1413G>A p.L471= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV63032499; called by muse, mutect2, varscan2
- NIBAN2 | c.213C>T p.F71= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1387040245, COSV100964843; called by muse, mutect2
- NKAIN1 | c.483C>T p.F161= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs944551795, COSV99744329; called by muse, mutect2, varscan2
- NLRP5 | c.2844C>A p.V948= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV101173281; called by muse, mutect2
- NPAS4 | c.486A>C p.A162= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100214697; called by muse, mutect2
- NT5C1A | c.210C>T p.I70= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99348200; called by muse, mutect2
- OVCH1 | c.696C>A p.A232= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100548177, COSV58959972; called by muse, mutect2
- P2RX1 | c.186C>T p.I62= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99844450; called by muse, mutect2
- PAG1 | c.240C>T p.S80= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99596873; called by muse, mutect2, varscan2
- PANK1 | c.159C>A p.P53= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100285417; called by muse, mutect2
- PCDHGB3 | c.1707C>A p.P569= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2
- PGA5 | c.672C>A p.G224= | Silent (SNP) | VAF 81/409 reads (20%) | catalogued as COSV100409237; called by muse, mutect2, varscan2
- PJVK | c.336G>A p.V112= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs200025341; called by muse, mutect2, varscan2
- PKHD1 | c.8133C>T p.V2711= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV100580717; called by muse, mutect2
- PLAT | c.1497C>A p.G499= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV99534902; called by muse, mutect2, varscan2
- PLEKHH2 | c.2892G>C p.L964= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV99174256; called by muse, mutect2, varscan2
- PRAME | c.291C>T p.F97= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs1401726578, COSV101286992; called by muse, mutect2, varscan2
- PRAMEF12 | c.243G>T p.V81= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV100742910; called by muse, mutect2
- PTGIS | c.1047C>T p.L349= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs987992184, COSV54835084, COSV54838389; called by muse, mutect2
- RADX | c.564C>T p.Y188= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100998706; called by muse, mutect2, varscan2
- RCBTB2 | c.270G>C p.R90= | Silent (SNP) | VAF 9/157 reads (6%) | catalogued as COSV100749519, COSV60649990; called by muse, mutect2
- RIN3 | c.1461G>T p.A487= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99378218; called by muse, mutect2, varscan2
- RMI1 | c.825A>T p.S275= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV100365981; called by muse, mutect2, varscan2
- RRP12 | c.1587G>T p.A529= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100212799; called by muse, mutect2, varscan2
- RUVBL1 | c.924C>T p.D308= | Silent (SNP) | VAF 48/80 reads (60%) | catalogued as rs1415593283, COSV100493996; called by muse, mutect2, varscan2
- SEL1L3 | c.2259G>A p.L753= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as COSV99339147; called by muse, mutect2
- SHOX2 | c.927C>G p.T309= (on ENST00000441443 / NM_006884.3; = p.T333= on NM_003030.4) | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as COSV101273726; called by muse, mutect2
- SLC1A7 | c.1629T>A p.A543= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100439272; called by muse, mutect2, varscan2
- SLC30A3 | c.843C>T p.T281= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs780943941, COSV99273363; called by muse, mutect2, varscan2
- SP100 | c.2274G>A p.E758= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs371571535; called by muse, mutect2, varscan2
- SPHKAP | c.3831C>G p.V1277= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV100763558; called by muse, mutect2, varscan2
- STARD6 | c.325C>A p.R109= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs200226447, COSV100323329; called by muse, mutect2, varscan2
- TCHHL1 | c.1929A>G p.P643= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as COSV100916488; called by muse, mutect2
- TNIK | c.28C>T p.L10= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1031380365, COSV99454205; called by muse, mutect2, varscan2
- TRPM2 | c.1593G>C p.L531= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100308012; called by muse, mutect2, varscan2
- UBA6 | c.1530C>T p.F510= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as COSV100451413; called by muse, mutect2
- UGT2B7 | c.1197A>G p.Q399= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs545832745, COSV100535049; called by muse, mutect2
- UNC13A | c.375G>T p.T125= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99406770; called by muse, mutect2, varscan2
- WWC2 | c.3270G>A p.L1090= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101330824; called by muse, mutect2, varscan2
- XIRP2 | c.5667C>T p.V1889= (on ENST00000628543; = p.V2064= on NM_152381.6) | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV99736965; called by muse, mutect2
- XRCC1 | c.75C>G p.L25= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99486135; called by muse, mutect2, varscan2
- ZFP42 | c.180T>A p.P60= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV100478524; called by muse, mutect2
- ZNF684 | c.300G>A p.L100= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101015869; called by muse, mutect2
- ZP4 | c.168A>T p.I56= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV100850479; called by muse, mutect2
- AL136982.4 | n.105G>C | RNA (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73849418 G>C | 5'Flank (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- ATP11A | c.*62C>G | 3'UTR (SNP) | VAF 4/63 reads (6%) | catalogued as COSV52107487, COSV99367138; called by muse, mutect2
- CAPRIN2 | c.2148+1597C>T | Intron (SNP) | VAF 14/122 reads (11%) | catalogued as COSV99195400; called by muse, mutect2, varscan2
- DNM1L | c.251-1521C>G | Intron (SNP) | VAF 17/193 reads (9%) | catalogued as COSV99845652; called by muse, mutect2
- GLOD4 | chr17:783112 C>A | 5'Flank (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100022367; called by muse, mutect2
- MAP3K20 | c.987+3975G>C | Intron (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100168647; called by muse, mutect2, varscan2
- PSG5 | c.431-2976A>T | Intron (SNP) | VAF 12/213 reads (6%) | catalogued as COSV61655540; called by muse, mutect2
- TTN | c.10360+3233G>A | Intron (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100589294; called by muse, mutect2, varscan2
